Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IV, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IV-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

OUTPATIENT

Clinical Diagnosis & History:

Bladder mass

Specimens Submitted:

1: Left lateral and anterior wall bladder tumor

DIAGNOSIS:

1. Left lateral and anterior wall bladder tumor:

Tumor Type:

Invasive urothelial carcinoma, NOS, with focal squamous differentiation

Histologic Grade:

High grade

ICD-0-3

Pattern of growth of the non-invasive component:

Flat (in situ carcinoma)

carcinoma, urothelial, NOS 8120/3

Path Site: bladder, wall, NOS C67.9

Local Invasion:

Muscularis propria

CQCF: bladder, wall, lateral C67.2

Vascular Invasion:

Not identified

lw 12/7/11

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received in Hank's solution, labelled "Left lateral and anterior wall bladder tumor" and consists of multiple pieces of irregular tan-brown soft tissue fragments measuring 1.3 X 1.1 X 0.6 cm in aggregate. The specimen is entirely submitted in two cassettes. TPS submitted.

Summary of Sections:

Part 1: Left lateral and anterior wall bladder tumor

Block	Sect. Site	PCs
2	{not entered}	12

Source: NCI Genomic Data Commons file 31825d87-5e78-4466-9d12-f4deda599d92 (TCGA-DK-A3IV.258903DE-CB30-4577-9571-C470256E21C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).